Somatic mutation profile of tumor specimen ALCH-ABN4-TTP1-A (aliquot ALCH-ABN4-TTP1-A-1-0-D-A488-36) from ALCHEMIST case ALCH-ABN4, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 68.1 years (24,884 days).
Specimen ALCH-ABN4-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a3f53bf8-1026-4ae0-9329-94fc3db1c4b8.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-ABN4-NB1-A (Blood Derived Normal), aliquot ALCH-ABN4-NB1-A-1-0-D-A488-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f074c869-581e-4d3d-8843-742cfd721fe2

The open-access MAF lists 169 somatic variants for this specimen: 118 protein-altering or splice-affecting, 31 silent, 20 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 100, Silent 31, Intron 8, Frame Shift Del 7, Nonsense Mutation 5, 5'UTR 4, Splice Site 4, RNA 4, 3'UTR 2, 3'Flank 1, 5'Flank 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- EGFR | c.2573T>G p.L858R | Missense Mutation (SNP) | VAF 2323/3174 reads (73%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs121434568, COSV51765161, COSV51854030; ClinVar: likely pathogenic / drug response / pathogenic; called by muse, mutect2, varscan2
- TP53 | c.796G>T p.G266* | Nonsense Mutation (SNP) | VAF 154/800 reads (19%) | hotspot (GDC flag); catalogued as rs1057519990, COSV52670619, COSV52672762, COSV52751844; called by mutect2, varscan2
- ABCA3 | c.2117T>A p.L706H | Missense Mutation (SNP) | VAF 94/621 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1226656475; called by muse, mutect2, varscan2
- ACVR1C | c.1366G>A p.V456I | Missense Mutation (SNP) | VAF 18/107 reads (17%) | SIFT tolerated (0.26); PolyPhen benign (0.022); catalogued as rs770708637; called by muse, mutect2, varscan2
- ADAMTS20 | c.5643+1G>A p.X1881_splice | Splice Site (SNP) | VAF 45/206 reads (22%) | catalogued as COSV67129390; called by muse, mutect2, varscan2
- AGGF1 | c.260A>G p.K87R | Missense Mutation (SNP) | VAF 161/940 reads (17%) | SIFT tolerated (0.39); PolyPhen benign (0.015); catalogued as rs753952728; called by muse, mutect2, varscan2
- APBB2 | c.272del p.G91Efs*10 | Frame Shift Del (DEL) | VAF 64/525 reads (12%) | catalogued as COSV55946288; called by mutect2, pindel, varscan2
- B4GALT3 | c.1067G>A p.R356H | Missense Mutation (SNP) | VAF 40/634 reads (6%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.021); catalogued as rs746359457, COSV60526872; called by muse, mutect2
- C3 | c.1327G>C p.A443P | Missense Mutation (SNP) | VAF 61/550 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.178); catalogued as CM165488; called by muse, mutect2, varscan2
- CEP131 | c.2071C>T p.R691C (on ENST00000269392 / NM_001319228.2; = p.R688C on NM_014984.4) | Missense Mutation (SNP) | VAF 53/288 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.857); catalogued as rs143625194; called by muse, mutect2, varscan2
- CSMD1 | c.1249C>A p.R417S (on ENST00000520002; = p.R416S on NM_033225.6) | Missense Mutation (SNP) | VAF 26/223 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.961); catalogued as COSV68191888; called by muse, mutect2, varscan2
- CYP4F12 | c.1094G>A p.R365H | Missense Mutation (SNP) | VAF 25/223 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.398); catalogued as rs760721349; called by muse, mutect2, varscan2
- FANCD2OS | c.238C>A p.R80S | Missense Mutation (SNP) | VAF 83/429 reads (19%) | SIFT deleterious (0.02); PolyPhen benign (0.017); catalogued as rs141930678; called by muse, mutect2, varscan2
- FRAS1 | c.5436G>A p.M1812I | Missense Mutation (SNP) | VAF 37/183 reads (20%) | SIFT tolerated (0.05); PolyPhen benign (0.021); catalogued as COSV53609617, COSV53619992; called by muse, mutect2, varscan2
- HGF | c.474C>A p.H158Q | Missense Mutation (SNP) | VAF 119/946 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs367553438; called by muse, mutect2, varscan2
- IQGAP1 | c.4285A>G p.I1429V | Missense Mutation (SNP) | VAF 111/696 reads (16%) | SIFT tolerated (0.59); PolyPhen benign (0); catalogued as rs1447565134; called by muse, mutect2, varscan2
- KDM5C | c.932G>A p.R311K | Missense Mutation (SNP) | VAF 75/218 reads (34%) | SIFT tolerated (0.09); PolyPhen benign (0.1); catalogued as COSV64766388; called by muse, mutect2, varscan2
- KIAA1217 | c.1099A>G p.I367V | Missense Mutation (SNP) | VAF 126/714 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.976); catalogued as COSV56820452; called by muse, mutect2, varscan2
- KLHL14 | c.1354C>T p.R452C | Missense Mutation (SNP) | VAF 122/810 reads (15%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.664); catalogued as rs773956260, COSV63830709; called by muse, mutect2, varscan2
- LCN6 | c.172G>T p.G58W | Missense Mutation (SNP) | VAF 33/172 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV100366559; called by muse, mutect2, varscan2
- LPIN3 | c.907G>A p.A303T | Missense Mutation (SNP) | VAF 64/429 reads (15%) | SIFT tolerated (0.36); PolyPhen benign (0.001); catalogued as rs1304818834; called by muse, mutect2, varscan2
- LRRC3C | c.796G>A p.E266K | Missense Mutation (SNP) | VAF 70/396 reads (18%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.958); catalogued as rs1048925159; called by muse, mutect2, varscan2
- MEP1B | c.983A>T p.E328V | Missense Mutation (SNP) | VAF 78/545 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.918); catalogued as COSV52497047; called by muse, mutect2, varscan2
- MRGPRG | c.409G>T p.V137L | Missense Mutation (SNP) | VAF 5/29 reads (17%) | SIFT deleterious (0.03); PolyPhen benign (0.034); catalogued as rs899976685; called by muse, mutect2
- MUC16 | c.5476G>A p.E1826K | Missense Mutation (SNP) | VAF 70/530 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.012); catalogued as rs772947821; called by muse, mutect2, varscan2
- MUC6 | c.4057G>C p.G1353R | Missense Mutation (SNP) | VAF 5/44 reads (11%) | SIFT tolerated, low confidence (0.29); PolyPhen benign (0.015); catalogued as COSV101424411; called by muse, mutect2
- NTM | c.602G>T p.C201F | Missense Mutation (SNP) | VAF 52/411 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100869673; called by muse, varscan2
- OR5AS1 | c.215G>T p.S72I | Missense Mutation (SNP) | VAF 11/50 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.168); catalogued as COSV57981885; called by muse, mutect2, varscan2
- OSTF1 | c.359-1G>A p.X120_splice | Splice Site (SNP) | VAF 44/216 reads (20%) | catalogued as rs1443341867; called by muse, mutect2, varscan2
- PDCL3 | c.668C>T p.S223L | Missense Mutation (SNP) | VAF 28/309 reads (9%) | SIFT tolerated (0.06); PolyPhen benign (0.083); catalogued as COSV99959410; called by muse, mutect2
- PDE10A | c.1872G>T p.E624D | Missense Mutation (SNP) | VAF 68/811 reads (8%) | SIFT tolerated (0.73); PolyPhen probably damaging (0.949); catalogued as rs760870734; called by muse, mutect2
- RBM10 | c.2330A>T p.H777L | Missense Mutation (SNP) | VAF 86/239 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61310374; called by muse, mutect2, varscan2
- RBM19 | c.431C>T p.A144V | Missense Mutation (SNP) | VAF 17/156 reads (11%) | SIFT tolerated (0.07); PolyPhen benign (0); catalogued as rs943188814; called by muse, mutect2, varscan2
- RFC1 | c.3220C>T p.P1074S (on ENST00000381897 / NM_001363496.2; = p.P1073S on NM_002913.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 50/258 reads (19%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.562); catalogued as COSV56461644, COSV56465924; called by muse, mutect2, varscan2
- SIPA1L3 | c.869G>T p.G290V | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.999); catalogued as rs1333256492; called by muse, mutect2, varscan2
- SNTA1 | c.620G>A p.R207Q | Missense Mutation (SNP) | VAF 86/536 reads (16%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs771180054, COSV54129826; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TIAM1 | c.4042G>A p.A1348T | Missense Mutation (SNP) | VAF 64/373 reads (17%) | SIFT tolerated (0.25); PolyPhen benign (0.005); catalogued as rs769275298, COSV54559451; called by muse, mutect2, varscan2
- TTBK1 | c.125del p.G42Afs*14 | Frame Shift Del (DEL) | VAF 32/193 reads (17%) | catalogued as COSV52489559; called by mutect2, pindel, varscan2
- TUBB6 | c.320C>A p.T107K | Missense Mutation (SNP) | VAF 8/22 reads (36%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.882); catalogued as COSV52313268, COSV52313274; called by muse, mutect2, varscan2
- VPS13A | c.6426G>T p.Q2142H | Missense Mutation (SNP) | VAF 22/260 reads (8%) | SIFT tolerated (0.12); PolyPhen benign (0.015); catalogued as COSV62436620; called by muse, mutect2
- A4GALT | c.1061G>T p.*354Lext*12 | Nonstop Mutation (SNP) | VAF 16/68 reads (24%) | called by muse, mutect2, varscan2
- APBA2 | c.1653G>C p.E551D | Missense Mutation (SNP) | VAF 90/673 reads (13%) | SIFT tolerated (0.34); PolyPhen benign (0.028); called by muse, mutect2, varscan2
- ATG2B | c.5123G>T p.R1708L | Missense Mutation (SNP) | VAF 36/286 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, varscan2
- BCL11B | c.1600G>T p.D534Y (on ENST00000357195 / NM_001282237.2; = p.D463Y on NM_022898.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 45/282 reads (16%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.706); called by muse, mutect2, varscan2
- CACNG3 | c.412_413insA p.A138Dfs*31 | Frame Shift Ins (INS) | VAF 46/301 reads (15%) | called by mutect2, pindel*, varscan2
- CCDC85A | c.482A>T p.E161V | Missense Mutation (SNP) | VAF 69/548 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- CDHR1 | c.1477G>A p.A493T | Missense Mutation (SNP) | VAF 35/160 reads (22%) | SIFT tolerated (0.35); PolyPhen benign (0.388); called by muse, mutect2, varscan2
- CEP250 | c.3512A>C p.Q1171P | Missense Mutation (SNP) | VAF 41/344 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.879); called by muse, mutect2, varscan2
- CFAP206 | c.1609T>C p.W537R | Missense Mutation (SNP) | VAF 23/168 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- CGAS | c.683_693delinsC p.V228Afs*9 | Frame Shift Del (DEL) | VAF 35/214 reads (16%) | called by pindel, varscan2*
- CLCN5 | c.1571_1617del p.I524Sfs*20 | Frame Shift Del (DEL) | VAF 71/268 reads (26%) | called by mutect2, pindel*
- CLIP2 | c.2273T>A p.L758Q | Missense Mutation (SNP) | VAF 43/250 reads (17%) | SIFT tolerated (0.49); PolyPhen possibly damaging (0.499); called by muse, mutect2, varscan2
- CROCC2 | c.3226G>A p.D1076N | Missense Mutation (SNP) | VAF 20/362 reads (6%) | SIFT deleterious (0.03); PolyPhen benign (0.218); called by muse, mutect2
- CSF1R | c.1358C>A p.P453Q | Missense Mutation (SNP) | VAF 34/188 reads (18%) | SIFT tolerated (0.17); PolyPhen benign (0.228); called by muse, mutect2, varscan2
- DDX28 | c.566G>T p.R189L | Missense Mutation (SNP) | VAF 14/75 reads (19%) | SIFT tolerated (0.13); PolyPhen benign (0.025); called by muse, mutect2, varscan2
- DNAH10 | c.873T>A p.S291R (on ENST00000409039; = p.S230R on NM_207437.3) | Missense Mutation (SNP) | VAF 90/383 reads (23%) | SIFT tolerated (0.42); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- EHD3 | c.286T>A p.S96T | Missense Mutation (SNP) | VAF 45/354 reads (13%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.665); called by muse, mutect2, varscan2
- ENTPD8 | c.841A>T p.T281S | Missense Mutation (SNP) | VAF 16/62 reads (26%) | SIFT tolerated (0.09); PolyPhen benign (0.098); called by muse, varscan2
- ESR1 | c.683C>A p.T228N | Missense Mutation (SNP) | VAF 77/899 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- EYA1 | c.273C>G p.N91K | Missense Mutation (SNP) | VAF 191/1052 reads (18%) | SIFT tolerated (0.26); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- FAT3 | c.134A>T p.H45L | Missense Mutation (SNP) | VAF 40/339 reads (12%) | SIFT deleterious (0.02); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- FSCB | c.395del p.Q132Rfs*11 | Frame Shift Del (DEL) | VAF 29/230 reads (13%) | called by mutect2, pindel, varscan2
- FSIP2 | c.15874C>T p.L5292F | Missense Mutation (SNP) | VAF 52/416 reads (13%) | SIFT deleterious (0.03); PolyPhen benign (0.007); called by muse, varscan2
- FST | c.316T>C p.C106R | Missense Mutation (SNP) | VAF 69/367 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- GBA2 | c.2441G>C p.S814T | Missense Mutation (SNP) | VAF 147/713 reads (21%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- HERC2 | c.1691C>G p.A564G | Missense Mutation (SNP) | VAF 31/281 reads (11%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- HIPK1 | c.1843G>T p.A615S | Missense Mutation (SNP) | VAF 131/690 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.111); called by muse, mutect2, varscan2
- IGHV1OR21-1 | c.246G>T p.K82N | Missense Mutation (SNP) | VAF 56/1098 reads (5%) | SIFT tolerated (0.08); PolyPhen benign (0.132); called by muse, mutect2
- KCNK10 | c.1304G>C p.G435A | Missense Mutation (SNP) | VAF 19/428 reads (4%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0); called by muse, mutect2
- KTN1 | c.2220del p.D741Mfs*4 | Frame Shift Del (DEL) | VAF 42/300 reads (14%) | called by mutect2, pindel, varscan2
- LAMA2 | c.2768G>T p.G923V | Missense Mutation (SNP) | VAF 58/792 reads (7%) | SIFT tolerated (0.13); PolyPhen benign (0.003); called by muse, mutect2
- LIMCH1 | c.2263A>G p.K755E | Missense Mutation (SNP) | VAF 19/403 reads (5%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.991); called by muse, mutect2
- LPA | c.4651T>A p.C1551S | Missense Mutation (SNP) | VAF 49/382 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, varscan2
- MED12 | c.6160C>T p.Q2054* | Nonsense Mutation (SNP) | VAF 136/325 reads (42%) | called by muse, varscan2
- MED23 | c.2751G>T p.W917C | Missense Mutation (SNP) | VAF 90/980 reads (9%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); called by muse, mutect2
- NLRP8 | c.367+1G>T p.X123_splice | Splice Site (SNP) | VAF 14/63 reads (22%) | called by muse, mutect2, varscan2
- NUDT7 | c.88G>T p.G30C | Missense Mutation (SNP) | VAF 27/248 reads (11%) | SIFT deleterious (0.04); PolyPhen benign (0.293); called by muse, mutect2, varscan2
- NUDT7 | c.89G>T p.G30V | Missense Mutation (SNP) | VAF 26/260 reads (10%) | SIFT tolerated (0.26); PolyPhen benign (0.003); called by muse, mutect2
- OR10P1 | c.67C>A p.L23M | Missense Mutation (SNP) | VAF 50/248 reads (20%) | SIFT tolerated (0.06); PolyPhen benign (0.365); called by muse, mutect2, varscan2
- OR1E2 | c.494C>T p.A165V | Missense Mutation (SNP) | VAF 120/508 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.968); called by muse, varscan2
- OR2C3 | c.320G>T p.W107L | Missense Mutation (SNP) | VAF 52/497 reads (10%) | SIFT tolerated (0.57); PolyPhen benign (0.086); called by muse, mutect2, varscan2
- OR52N4 | c.880G>T p.V294F | Missense Mutation (SNP) | VAF 56/492 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.846); called by muse, mutect2, varscan2
- OR5L1 | c.635T>A p.M212K | Missense Mutation (SNP) | VAF 45/434 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.139); called by muse, mutect2, varscan2
- OTOG | c.2353G>A p.E785K | Missense Mutation (SNP) | VAF 43/317 reads (14%) | SIFT tolerated (0.08); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- OXSR1 | c.1277G>T p.G426V | Missense Mutation (SNP) | VAF 88/449 reads (20%) | SIFT tolerated (0.25); PolyPhen benign (0); called by muse, mutect2, varscan2
- PCDH11X | c.2004C>A p.D668E | Missense Mutation (SNP) | VAF 127/441 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- PCDHB12 | c.1945G>T p.E649* | Nonsense Mutation (SNP) | VAF 48/554 reads (9%) | called by muse, mutect2, varscan2
- PLEKHG2 | c.2878G>T p.G960C | Missense Mutation (SNP) | VAF 44/211 reads (21%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.436); called by muse, mutect2, varscan2
- POTED | c.380C>T p.A127V | Missense Mutation (SNP) | VAF 176/516 reads (34%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.483); called by muse, mutect2, varscan2
- PPP1R2B | c.218C>A p.P73H | Missense Mutation (SNP) | VAF 142/1007 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.296); called by muse, mutect2, varscan2
- PRR23C | c.196G>T p.G66C | Missense Mutation (SNP) | VAF 22/69 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PSME4 | c.2960A>T p.Q987L | Missense Mutation (SNP) | VAF 82/410 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PTPRA | c.761A>G p.Q254R | Missense Mutation (SNP) | VAF 40/220 reads (18%) | SIFT tolerated (0.06); PolyPhen benign (0.063); called by muse, mutect2, varscan2
- RAD54L | c.1610+2T>A p.X537_splice | Splice Site (SNP) | VAF 122/712 reads (17%) | called by muse, mutect2, varscan2
- RNGTT | c.989G>T p.R330L | Missense Mutation (SNP) | VAF 30/267 reads (11%) | SIFT tolerated (0.42); PolyPhen benign (0.079); called by muse, mutect2, varscan2
- SAMD9 | c.49G>C p.E17Q | Missense Mutation (SNP) | VAF 55/224 reads (25%) | SIFT deleterious (0.04); PolyPhen benign (0.12); called by muse, mutect2, varscan2
- SHISA9 | c.449C>A p.T150N | Missense Mutation (SNP) | VAF 43/244 reads (18%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SLC25A24 | c.97C>G p.R33G | Missense Mutation (SNP) | VAF 103/633 reads (16%) | SIFT tolerated (0.41); PolyPhen benign (0.112); called by muse, mutect2, varscan2
- SLC30A5 | c.1700A>G p.H567R | Missense Mutation (SNP) | VAF 75/444 reads (17%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- SLC4A10 | c.654del p.M218Ifs*84 (on ENST00000446997 / NM_001354461.2; = p.M218Ifs*75 on NM_022058.4 and 5 other RefSeq transcripts) | Frame Shift Del (DEL) | VAF 44/382 reads (12%) | called by mutect2, pindel*, varscan2
- SNAPC1 | c.949G>T p.G317* | Nonsense Mutation (SNP) | VAF 56/292 reads (19%) | called by muse, varscan2
- SOGA1 | c.3338A>T p.Q1113L | Missense Mutation (SNP) | VAF 15/91 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.487); called by muse, varscan2
- SPRR2G | c.133C>A p.H45N | Missense Mutation (SNP) | VAF 70/641 reads (11%) | PolyPhen benign (0); called by muse, mutect2, varscan2
- SYNE2 | c.17185C>T p.Q5729* | Nonsense Mutation (SNP) | VAF 122/747 reads (16%) | called by muse, mutect2, varscan2
- SYT1 | c.437T>A p.L146H | Missense Mutation (SNP) | VAF 64/344 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- TAF5L | c.653G>A p.S218N | Missense Mutation (SNP) | VAF 35/179 reads (20%) | SIFT tolerated (0.51); PolyPhen benign (0); called by muse, mutect2, varscan2
- TAF5L | c.527T>C p.I176T | Missense Mutation (SNP) | VAF 61/397 reads (15%) | SIFT tolerated (0.06); PolyPhen benign (0.101); called by muse, mutect2, varscan2
- TLR3 | c.1678G>T p.G560C | Missense Mutation (SNP) | VAF 60/309 reads (19%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.968); called by muse, mutect2, varscan2
- TNR | c.3252G>C p.E1084D | Missense Mutation (SNP) | VAF 32/219 reads (15%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.765); called by muse, mutect2, varscan2
- TRPM7 | c.5273A>T p.Y1758F | Missense Mutation (SNP) | VAF 63/420 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- VCX | c.299A>T p.Q100L | Missense Mutation (SNP) | VAF 136/1192 reads (11%) | SIFT tolerated (0.07); PolyPhen benign (0.003); called by muse, varscan2
- VN1R2 | c.1006G>C p.V336L | Missense Mutation (SNP) | VAF 59/238 reads (25%) | SIFT tolerated (0.16); PolyPhen benign (0.175); called by muse, mutect2, varscan2
- XYLT1 | c.1369A>T p.R457W | Missense Mutation (SNP) | VAF 67/336 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ZBTB14 | c.145G>A p.A49T | Missense Mutation (SNP) | VAF 56/438 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- ZFP90 | c.808A>C p.T270P | Missense Mutation (SNP) | VAF 54/240 reads (23%) | SIFT tolerated (0.07); PolyPhen benign (0.354); called by muse, mutect2, varscan2
- ZNF189 | c.278A>G p.Q93R | Missense Mutation (SNP) | VAF 13/238 reads (5%) | SIFT tolerated (0.5); PolyPhen benign (0.017); called by muse, mutect2
- ZNF474 | c.420G>T p.Q140H | Missense Mutation (SNP) | VAF 79/486 reads (16%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.702); called by muse, mutect2, varscan2
- ZNF608 | c.2677G>T p.A893S | Missense Mutation (SNP) | VAF 80/449 reads (18%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.953); called by muse, mutect2, varscan2
- BBS2 | c.84C>T p.H28= | Silent (SNP) | VAF 54/249 reads (22%) | called by muse, mutect2, varscan2
- CA4 | c.408C>A p.A136= | Silent (SNP) | VAF 35/191 reads (18%) | called by muse, mutect2, varscan2
- CCDC126 | c.339A>G p.A113= | Silent (SNP) | VAF 123/613 reads (20%) | called by muse, mutect2, varscan2
- CSHL1 | c.495G>T p.L165= (on ENST00000309894 / NM_022581.3; = p.L71= on NM_001318.4) | Silent (SNP) | VAF 114/664 reads (17%) | called by muse, mutect2, varscan2
- CTRB2 | c.120C>A p.A40= | Silent (SNP) | VAF 21/131 reads (16%) | called by muse, varscan2
- DLC1 | c.972C>A p.T324= | Silent (SNP) | VAF 57/349 reads (16%) | called by muse, mutect2, varscan2
- EPHA6 | c.507A>G p.V169= | Silent (SNP) | VAF 44/230 reads (19%) | catalogued as COSV101066022, COSV67595678; called by muse, varscan2
- FRMPD4 | c.1422C>T p.S474= | Silent (SNP) | VAF 11/120 reads (9%) | catalogued as rs776319989; called by muse, mutect2
- GALNT17 | c.711T>A p.A237= | Silent (SNP) | VAF 25/141 reads (18%) | catalogued as COSV61153466; called by muse, mutect2, varscan2
- ITFG1 | c.114G>T p.T38= | Silent (SNP) | VAF 141/730 reads (19%) | called by muse, mutect2, varscan2
- MRC1 | c.1500C>T p.V500= | Silent (SNP) | VAF 42/713 reads (6%) | catalogued as rs1283476394; called by muse, mutect2
- MUC16 | c.15810C>A p.T5270= | Silent (SNP) | VAF 32/196 reads (16%) | called by muse, mutect2, varscan2
- MUC22 | c.3135C>A p.T1045= | Silent (SNP) | VAF 84/559 reads (15%) | called by muse, mutect2, varscan2
- NLRP2 | c.1011G>T p.R337= | Silent (SNP) | VAF 15/92 reads (16%) | called by muse, mutect2, varscan2
- NRXN2 | c.1974G>C p.V658= | Silent (SNP) | VAF 14/132 reads (11%) | called by muse, mutect2, varscan2
- OR2W3 | c.402G>T p.V134= | Silent (SNP) | VAF 18/151 reads (12%) | catalogued as COSV64458013; called by muse, mutect2, varscan2
- OR5D16 | c.552C>T p.S184= | Silent (SNP) | VAF 35/313 reads (11%) | called by muse, mutect2, varscan2
- PCDH10 | c.2241C>T p.N747= | Silent (SNP) | VAF 76/360 reads (21%) | catalogued as rs779306908; called by muse, varscan2
- RREB1 | c.1719G>T p.A573= | Silent (SNP) | VAF 11/97 reads (11%) | catalogued as COSV58555027; called by muse, mutect2, varscan2
- RYR2 | c.645C>A p.A215= | Silent (SNP) | VAF 70/333 reads (21%) | called by muse, mutect2, varscan2
- RYR2 | c.1926G>A p.L642= | Silent (SNP) | VAF 107/565 reads (19%) | called by muse, mutect2, varscan2
- SLC45A2 | c.792A>T p.G264= | Silent (SNP) | VAF 99/477 reads (21%) | called by muse, mutect2, varscan2
- SOX11 | c.1239C>T p.F413= | Silent (SNP) | VAF 16/320 reads (5%) | catalogued as rs1472789802; called by muse, mutect2
- SP8 | c.1323C>T p.G441= (on ENST00000361443 / NM_198956.4; = p.G459= on NM_182700.6) | Silent (SNP) | VAF 42/678 reads (6%) | catalogued as COSV100815297; called by muse, mutect2
- SUPT20HL1 | c.1425C>T p.S475= | Silent (SNP) | VAF 141/428 reads (33%) | called by muse, mutect2, varscan2
- TERT | c.1896G>A p.P632= | Silent (SNP) | VAF 82/490 reads (17%) | catalogued as rs140056333; ClinVar: likely benign; called by muse, mutect2, varscan2
- THSD7A | c.2574G>A p.Q858= | Silent (SNP) | VAF 96/396 reads (24%) | called by muse, mutect2, varscan2
- TLN2 | c.3789G>T p.R1263= | Silent (SNP) | VAF 29/270 reads (11%) | called by muse, mutect2, varscan2
- TP53 | c.795G>T p.L265= | Silent (SNP) | VAF 158/828 reads (19%) | catalogued as COSV52661636, COSV52730242, COSV52895662, COSV99474023; called by muse, mutect2, varscan2
- TRAV18 | c.177A>T p.L59= | Silent (SNP) | VAF 73/584 reads (13%) | called by muse, mutect2, varscan2
- WASF3 | c.912G>A p.P304= | Silent (SNP) | VAF 22/121 reads (18%) | catalogued as rs141429361; called by mutect2, varscan2
- AC114482.1 | chr1:84631627 C>T | 3'Flank (SNP) | VAF 60/397 reads (15%) | catalogued as rs766359787; called by muse, mutect2, varscan2
- ALDH7A1 | c.872-20T>C | Intron (SNP) | VAF 75/396 reads (19%) | called by muse, mutect2, varscan2
- ANAPC1P2 | n.1152C>T | RNA (SNP) | VAF 44/1434 reads (3%) | catalogued as rs1444933224; called by muse, mutect2
- CFAP20DC | c.198-16928T>A | Intron (SNP) | VAF 50/220 reads (23%) | called by muse, mutect2, varscan2
- CHCHD2P9 | n.10G>T | RNA (SNP) | VAF 14/121 reads (12%) | called by muse, mutect2, varscan2
- CHRNA4 | c.*3042G>A | 3'UTR (SNP) | VAF 6/19 reads (32%) | called by muse, mutect2, varscan2
- DNM1P46 | n.997C>A | RNA (SNP) | VAF 37/180 reads (21%) | called by muse, mutect2, varscan2
- FAM76A | c.147-2363G>T | Intron (SNP) | VAF 6/43 reads (14%) | called by muse, varscan2
- MAPK8 | c.-17A>G | 5'UTR (SNP) | VAF 104/655 reads (16%) | called by muse, mutect2, varscan2
- MMP26 | c.-145+93135G>A | Intron (SNP) | VAF 55/262 reads (21%) | called by muse, mutect2, varscan2
- NOBOX | c.210+883C>T | Intron (SNP) | VAF 39/229 reads (17%) | called by muse, mutect2, varscan2
- RCC1 | c.-314G>T | 5'UTR (SNP) | VAF 38/408 reads (9%) | called by muse, mutect2
- RFX4 | c.-26del | 5'UTR (DEL) | VAF 8/61 reads (13%) | catalogued as rs751490680; called by mutect2, pindel, varscan2
- SNORD115-8 | n.46C>A | RNA (SNP) | VAF 38/594 reads (6%) | called by muse, mutect2
- SRGAP1 | c.1408+107A>G | Intron (SNP) | VAF 92/444 reads (21%) | called by muse, mutect2, varscan2
- SYPL2 | c.-22G>T | 5'UTR (SNP) | VAF 18/153 reads (12%) | called by muse, mutect2, varscan2
- TRAC | c.*311A>T | 3'UTR (SNP) | VAF 40/218 reads (18%) | called by muse, mutect2, varscan2
- UGT1A7 | c.855+7780C>A | Intron (SNP) | VAF 43/405 reads (11%) | called by muse, mutect2, varscan2
- ZCWPW1 | c.361+39C>T | Intron (SNP) | VAF 17/101 reads (17%) | called by muse, varscan2
- ZNF252P | chr8:145003232 C>T | 5'Flank (SNP) | VAF 104/598 reads (17%) | catalogued as rs1376104145; called by muse, mutect2, varscan2
